Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A3A8, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A3A8-01A (Primary Tumor).

Patient Key:

Surgical date:

TISSUE DESCRIPTION:

Gallbladder (10.3 x 5.2 x 2 cm), cm), pericholedochal lymph node (3.2 x 2.3 x 0.7 cm), spleen 165 grams, 11.2 x 6.5 x 4.2 cm) and right lobe liver (1110 grams, 17.5 x 14.5 x 8 cm). A1, B1, C1, D1, D2, D3, D4

DIAGNOSIS:

Liver, right lobe, resection: Grade 2 (of 4) hepatocellular carcinoma, usual type, forming a multinodular 7.5 x 5.8 x 5 cm mass. The tumor is located in the right lobe. The hepatic capsule is free of tumor. The surgical margins are free of tumor, the clearance being 0.1 cm microscopically. Extratumoral vascular invasion is not identified. The tumor is entirely encapsulated without capsular tumor extension.

Spleen, excision: Without diagnostic abnormality.

Lymph node, pericholedochal, excision: A single benign lymph node.

Gallbladder, cholecystectomy: Chronic cholecystitis. No stones are present.
(Seen with

ADDENDUM:

Immunohistochemical studies performed on paraffin-embedded sections of the liver show the neoplastic cells are negative for insulin.

ICD-O-3
carcinoma, hepatocellular, NOS 8170/3
Site: Liver C22.0
JW 9/22/11

IHPAA Discrepancy		X

Source: NCI Genomic Data Commons file 024d3152-ceff-4041-b628-688ef214058e (TCGA-DD-A3A8.5D143B3D-AC64-4C1C-A276-D12111750C67.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).